Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A6EQ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A6EQ-01A (Primary Tumor).

ICD-0-3

Carcinoma, squamous cell
keratinizing NOS 8071/3
Site Larynx C32.9
QW 5/24/13

Department of Cancer Pathology

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge: Surgery and Laryngological Oncology Dept.

Physician in charge:

Clinical diagnosis (suspicion) Laryngeal carcinoma

Date of admission:

Material:

1) Material: larynx. Please mark surgical margins - lower (trachea). Method of collection: Collection of specimens for laboratory examination

Histopathological diagnosis

Examination performed on:

Invasive keratinising squamous cell carcinoma (G3) of the larynx.

Incision lines free of neoplastic lesions.

pT3. (8071/3 T-24100)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Surgical specimen sized 9.5 x 7.0 x 3.5cm, including larynx with the hyoid bone and part of the trachea 1.5 cm in length. Tumour found in the glottal region, sized 4.5 x 2.5 x 1.2cm invading the subglottal region, glottis, supraglottal region, aryepiglottic fold on the left side.

Assistant:

Pathologist:

Edited

Results of intraoperative examination:

Examination performed on:

Margins at the side of 1 wire and 2 wires (top) cancerous lesions.

Final reply to be given after the analysis of paraffin specimens.

Assistant:

Pathologist:

Edited

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 7ebd18ee-fddd-4ec4-8553-473aa2d831c0 (TCGA-D6-A6EQ.E3C55935-DC6F-40F9-B529-E0D39775AD9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).